Somatic mutation profile of tumor specimen TCGA-14-0862-01B (aliquot TCGA-14-0862-01B-01D-1845-08) from TCGA case TCGA-14-0862, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,179 days).
Specimen TCGA-14-0862-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 173715dc-0eae-47d0-9da0-37f5285466db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0862-10C (Blood Derived Normal), aliquot TCGA-14-0862-10C-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b1abb13-ebed-4ced-9ccb-b967a30136f9

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 3, In Frame Del 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCOLN1 | c.984+1G>A p.X328_splice | Splice Site (SNP) | VAF 15/59 reads (25%) | catalogued as rs767950930, COSV51176968; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1137A>T p.K379N (on ENST00000521381 / NM_181523.3; = p.K109N on NM_181504.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57132536; called by muse, mutect2, varscan2
- ADCY9 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53577391; called by muse, mutect2
- ARHGAP25 | c.1906G>A p.V636I (on ENST00000409202 / NM_001007231.3; = p.V628I on NM_014882.3) | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.173); catalogued as COSV54904213; called by muse, mutect2, varscan2
- BMP5 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs148184427; called by muse, mutect2, varscan2
- CLIP1 | c.1865T>A p.L622Q (on ENST00000620786 / NM_001247997.1; = p.L611Q on NM_002956.2) | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV56803904; called by muse, mutect2, varscan2
- CRYM | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54831970; called by muse, mutect2, varscan2
- CXXC5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 68/223 reads (30%) | catalogued as COSV56793875; called by muse, mutect2, varscan2
- DCAF12L2 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs986702521, COSV63582375, COSV63582543; called by muse, mutect2, varscan2
- DSC1 | c.2167T>A p.C723S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.654); catalogued as COSV57147547; called by muse, mutect2
- FEZ1 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); catalogued as COSV54029600; called by muse, mutect2, varscan2
- FLG2 | c.3878A>G p.H1293R | Missense Mutation (SNP) | VAF 176/481 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV66169799; called by muse, mutect2, varscan2
- FRMD7 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as CM163892, COSV53746346, COSV53747183; called by muse, mutect2, varscan2
- HHIPL2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs753929029, COSV58564406; called by muse, mutect2, varscan2
- LZTR1 | c.1843_1845del p.K615del | In Frame Del (DEL) | VAF 41/107 reads (38%) | catalogued as rs746246349; called by mutect2, pindel, varscan2
- MAP3K19 | c.3390C>A p.C1130* | Nonsense Mutation (SNP) | VAF 31/115 reads (27%) | catalogued as COSV59640200; called by muse, mutect2, varscan2
- MID1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV58196134; called by muse, mutect2, varscan2
- MN1 | c.3088G>A p.G1030S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1480513294, COSV56559482; called by muse, mutect2, varscan2
- MON2 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV54809534; called by muse, mutect2, varscan2
- MUC16 | c.37418G>A p.R12473K | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV67459769; called by muse, mutect2, varscan2
- NEK4 | c.1620_1622del p.R541del | In Frame Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs1187367558; called by pindel, varscan2
- NTN1 | c.1195A>T p.K399* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51484098; called by muse, mutect2, varscan2
- OR11H12 | c.461A>C p.H154P | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs757442033, COSV73569072, COSV73569322; called by muse, mutect2, varscan2
- OR7G2 | c.710T>C p.L237S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV59688293; called by muse, mutect2, varscan2
- PCDHB12 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs1297969778, COSV53395290; called by muse, mutect2, varscan2
- PCDHGB6 | c.1182T>G p.I394M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV53940361; called by muse, mutect2, varscan2
- PELI1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV62730291; called by muse, mutect2, varscan2
- PKD2 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs754868200, COSV52939212; called by muse, mutect2, varscan2
- POU4F2 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV55585307; called by muse, mutect2, varscan2
- TCHP | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as rs746252789, COSV57165851; called by muse, mutect2, varscan2
- TLR2 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs764797246, COSV52605383; called by muse, mutect2, varscan2
- TMCO5A | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs138045481; called by muse, mutect2, varscan2
- WSCD2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs766005863, COSV54583535; called by muse, mutect2, varscan2
- ZNF99 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.105); catalogued as COSV68056015; called by muse, mutect2, varscan2
- HNF1B | c.1583T>C p.F528S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- REXO1 | c.864_869del p.D288_S289del | In Frame Del (DEL) | VAF 12/72 reads (17%) | called by pindel, varscan2
- AKAP8 | c.345T>C p.G115= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV54103250; called by mutect2, varscan2
- CNTNAP2 | c.3132G>A p.P1044= | Silent (SNP) | VAF 58/112 reads (52%) | catalogued as rs761663690, COSV62146496, COSV62147352; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FCGBP | c.11232G>A p.V3744= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- HHLA2 | c.819C>T p.Y273= | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as COSV100755499, COSV63318101; called by muse, mutect2, varscan2
- KCNG1 | c.246C>T p.D82= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs773495497, COSV65369515; called by muse, mutect2, varscan2
- OR1L1 | c.780G>A p.P260= (on ENST00000373686; = p.P210= on NM_001005236.3) | Silent (SNP) | VAF 66/186 reads (35%) | catalogued as rs560776179, COSV58935916; called by muse, mutect2, varscan2
- PRKCD | c.1503G>A p.G501= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV57849534; called by muse, mutect2, varscan2
- SAG | c.519C>T p.S173= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as rs771893652, COSV68591392; called by muse, mutect2, varscan2
- TMC8 | c.456G>A p.Q152= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs1342243840, COSV59210287; called by muse, mutect2, varscan2
- USP8 | c.2712T>C p.F904= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV56165484; called by muse, mutect2, varscan2
- VWF | c.3804C>T p.H1268= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs773863759, COSV54625178; called by muse, mutect2, varscan2
